Somatic mutation profile of tumor specimen TCGA-AA-3972-01A (aliquot TCGA-AA-3972-01A-01W-0995-10) from TCGA case TCGA-AA-3972, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 72.2 years (26,360 days).
Specimen TCGA-AA-3972-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c27619e7-3d5d-4c4d-a5ff-8543e2c3952a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3972-10A (Blood Derived Normal), aliquot TCGA-AA-3972-10A-01W-0999-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f244745-d57d-4d87-aac4-a7e955f6004e

The open-access MAF lists 102 somatic variants for this specimen: 71 protein-altering or splice-affecting, 29 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 29, Frame Shift Ins 6, Splice Region 3, Nonsense Mutation 3, Splice Site 3, Frame Shift Del 2, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 66/121 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACKR2 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 60/323 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs371119755; called by muse, mutect2, varscan2
- BSN | c.2437G>A p.D813N | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs757466787, COSV56515563; called by muse, mutect2, varscan2
- CASP14 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 21/87 reads (24%) | catalogued as rs546136139, COSV55666280; called by muse, mutect2, varscan2
- CASZ1 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs748445376, COSV59736622; called by muse, mutect2, varscan2
- CWC27 | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66885050; called by muse, mutect2, varscan2
- DGKI | c.2953G>A p.E985K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.063); catalogued as rs778003452, COSV55940907; called by muse, mutect2, varscan2
- DPYSL3 | c.1490G>A p.G497D | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV58325589; called by muse, mutect2
- DYNC2H1 | c.10946G>A p.R3649H | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.035); catalogued as rs753691638, COSV62100295; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELOVL2 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 97/266 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs758207633, COSV61154728; called by muse, mutect2, varscan2
- ELOVL4 | c.369G>A p.R123= | Splice Region (SNP) | VAF 7/38 reads (18%) | catalogued as COSV63953618; called by muse, mutect2, varscan2
- ENTPD3 | c.286+1G>T p.X96_splice | Splice Site (SNP) | VAF 10/46 reads (22%) | catalogued as rs546810984; called by muse, mutect2, varscan2
- EPG5 | c.6167G>A p.R2056Q | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs753386481; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EVC | c.661C>A p.L221M | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53831118; called by muse, mutect2, varscan2
- FCHSD2 | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as COSV60808170; called by muse, mutect2, varscan2
- FKBP11 | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs368324438; called by muse, mutect2, varscan2
- FN1 | c.5695G>A p.A1899T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.809); catalogued as rs573992192, COSV60547894; called by muse, mutect2, varscan2
- GABRA4 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs770775489, COSV51921952; called by muse, mutect2, varscan2
- GABRB3 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs777882335, COSV54663217; called by muse, mutect2, varscan2
- GLI3 | c.3133G>A p.V1045M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.513); catalogued as rs1166711228, COSV67887103; called by muse, mutect2, varscan2
- GUCA2B | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs538392274, COSV65367978; called by muse, mutect2, varscan2
- HAPLN1 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as rs773037636, COSV57145694; called by muse, mutect2, varscan2
- HDAC9 | c.478A>C p.T160P | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1410934368; called by muse, mutect2, varscan2
- HERC2 | c.6989G>A p.R2330Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.163); catalogued as rs1223906422, COSV55316742; called by muse, mutect2, varscan2
- KL | c.1123T>G p.L375V | Missense Mutation (SNP) | VAF 48/293 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV66308417; called by muse, mutect2
- LGI1 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs760266576, COSV65057776; called by muse, mutect2, varscan2
- MAK | c.159T>C p.S53= | Splice Region (SNP) | VAF 6/10 reads (60%) | catalogued as COSV57564794; called by muse, mutect2, varscan2
- MOS | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1563357863; called by muse, mutect2, varscan2
- NOTCH3 | c.1144G>A p.G382S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM035644; called by muse, mutect2, varscan2
- OR6C76 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.15); catalogued as rs1565685678, COSV60389223; called by muse, mutect2, varscan2
- OR8K5 | c.358T>A p.Y120N | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV57888403; called by muse, mutect2, varscan2
- PDS5A | c.1798C>T p.P600S | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV57828159; called by muse, varscan2
- PHYHIP | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58688340; called by mutect2, varscan2
- PLCG1 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs756870964, COSV54817147; called by muse, mutect2, varscan2
- PTPRM | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1237614240; called by muse, mutect2, varscan2
- SEC11C | c.496A>G p.I166V | Missense Mutation (SNP) | VAF 192/261 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1568068327; called by muse, mutect2, varscan2
- SFMBT2 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as rs755947896, COSV62816735; called by muse, mutect2, varscan2
- SGCZ | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs139184216, COSV101167818; called by muse, mutect2, varscan2
- SMC1B | c.2369G>A p.R790H | Missense Mutation (SNP) | VAF 46/56 reads (82%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs747788367, COSV100663121; called by muse, mutect2, varscan2
- TNR | c.2069G>A p.R690Q | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.313); catalogued as rs749424178, COSV104374995; called by muse, mutect2
- TTN | c.70603C>T p.R23535C (on ENST00000591111; = p.R16111C on NM_003319.4) | Missense Mutation (SNP) | VAF 28/46 reads (61%) | PolyPhen probably damaging (0.998); catalogued as rs368339903, COSV100612064, COSV59999579; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP2 | c.704C>T p.T235M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs369895568; called by muse, mutect2, varscan2
- WDR48 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as rs1446857989, COSV56531261; called by muse, mutect2, varscan2
- YLPM1 | c.2371G>A p.D791N | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as rs778282189, COSV53115203; called by muse, mutect2, varscan2
- ZNF208 | c.1139G>C p.W380S | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as COSV68103193; called by muse, mutect2, varscan2
- ZNF595 | c.60T>G p.C20W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100227746, COSV59548677; called by muse, mutect2, varscan2
- ADAM29 | c.2094dup p.K699* | Frame Shift Ins (INS) | VAF 16/38 reads (42%) | called by pindel, varscan2
- ADAM29 | c.2100A>C p.K700N | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.766); called by muse, varscan2
- ADCY9 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ALMS1 | c.2480A>G p.D827G | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- APC | c.2544del p.D849Ifs*12 | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | called by mutect2, pindel, varscan2
- AXIN2 | c.1044dup p.L349Sfs*25 | Frame Shift Ins (INS) | VAF 42/73 reads (58%) | called by mutect2, pindel, varscan2
- CASP4 | c.815C>A p.P272Q | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- FAT1 | c.713G>A p.S238N | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GABRB2 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRIK2 | c.863_864del p.Q288Rfs*6 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | called by mutect2, pindel, varscan2
- INTS3 | c.1518C>T p.V506= | Splice Region (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- IPO11 | c.1782+1G>T p.X594_splice | Splice Site (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- ISL1 | c.629T>A p.M210K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- MFSD5 | c.421_422insGGGGA p.T141Rfs*45 | Frame Shift Ins (INS) | VAF 23/70 reads (33%) | called by mutect2, pindel, varscan2
- MRC1 | c.637+1G>A p.X213_splice | Splice Site (SNP) | VAF 26/139 reads (19%) | called by muse, mutect2, varscan2
- MYBL2 | c.1900G>A p.G634S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- NCBP2 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.385); called by muse, mutect2
- RBM33 | c.842G>A p.G281D | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- RHOA | c.253dup p.S85Ffs*6 | Frame Shift Ins (INS) | VAF 9/32 reads (28%) | called by mutect2, pindel, varscan2
- RNF113B | c.633C>A p.C211* | Nonsense Mutation (SNP) | VAF 46/68 reads (68%) | called by muse, mutect2, varscan2
- SACS | c.7760C>T p.A2587V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, varscan2
- ST18 | c.1015A>G p.R339G | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.526); called by muse, mutect2
- TSG101 | c.860dup p.N287Kfs*10 | Frame Shift Ins (INS) | VAF 45/149 reads (30%) | called by mutect2, pindel, varscan2
- ZHX1 | c.2002dup p.T668Nfs*3 | Frame Shift Ins (INS) | VAF 20/57 reads (35%) | called by mutect2, varscan2
- ZNF616 | c.329A>C p.E110A | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ACTR6 | c.177T>C p.P59= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- ARHGEF5 | c.1308G>A p.Q436= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as COSV50208904; called by muse, mutect2, varscan2
- ASAP1 | c.2526C>A p.P842= | Silent (SNP) | VAF 191/406 reads (47%) | catalogued as COSV63046759; called by muse, mutect2, varscan2
- B9D1 | c.558G>A p.G186= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV52069325; called by muse, mutect2, varscan2
- CCR2 | c.816C>T p.F272= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as rs758746375, COSV52748154; called by muse, mutect2
- CDON | c.1005T>G p.V335= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV54996655; called by muse, varscan2
- COL4A4 | c.2241C>T p.P747= | Silent (SNP) | VAF 23/31 reads (74%) | catalogued as rs374510402; called by muse, mutect2, varscan2
- DLGAP2 | c.2688C>T p.N896= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1292720010, COSV70096670; called by muse, mutect2, varscan2
- FAM169A | c.306G>A p.E102= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as rs1474602207, COSV65846310; called by muse, mutect2, varscan2
- ICE1 | c.1762C>T p.L588= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV56822124; called by muse, mutect2, varscan2
- IL10RB | c.168C>T p.Y56= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV51614876; called by muse, mutect2, varscan2
- KSR2 | c.1722C>A p.I574= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV56669622; called by muse, mutect2, varscan2
- MPHOSPH8 | c.2352C>T p.I784= | Silent (SNP) | VAF 82/902 reads (9%) | catalogued as COSV64055115; called by muse, mutect2
- MUC16 | c.31968C>T p.V10656= | Silent (SNP) | VAF 182/931 reads (20%) | catalogued as rs1409293152, COSV67456951; called by muse, mutect2, varscan2
- MUC16 | c.29871C>T p.T9957= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV67456955; called by muse, mutect2, varscan2
- MYOF | c.4662G>A p.T1554= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs370636726; called by muse, mutect2, varscan2
- PARK7 | c.486C>T p.F162= | Silent (SNP) | VAF 52/78 reads (67%) | catalogued as rs777440876, COSV58579654; called by muse, mutect2, varscan2
- PCDHA13 | c.1638C>A p.G546= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV56530149; called by muse, mutect2
- PCDHB6 | c.636C>T p.I212= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs782395304, COSV50692536; called by muse, mutect2, varscan2
- RHOT1 | c.483C>T p.Y161= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as rs201021051, COSV61714825; called by muse, varscan2
- RIMS2 | c.1342T>C p.L448= (on ENST00000666250 / NM_001348490.2; = p.L256= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV51669105, COSV51676746; called by muse, mutect2, varscan2
- RNF220 | c.1116T>C p.G372= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as rs777588828, COSV59190229; called by muse, mutect2, varscan2
- RXFP3 | c.402C>T p.T134= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs1297615538, COSV57504881; called by muse, mutect2, varscan2
- SLC16A14 | c.657C>T p.N219= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV54617753; called by muse, mutect2, varscan2
- SPAG5 | c.3054A>G p.E1018= | Silent (SNP) | VAF 4/17 reads (24%) | called by muse, varscan2
- SREBF2 | c.1572C>T p.F524= | Silent (SNP) | VAF 13/19 reads (68%) | catalogued as rs199689929, COSV63330891; called by muse, mutect2, varscan2
- SYNM | c.1821C>T p.T607= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as rs782502643, COSV60368277; called by muse, mutect2, varscan2
- SYNPO2 | c.2793G>A p.P931= | Silent (SNP) | VAF 14/17 reads (82%) | catalogued as rs753637222, COSV61108746; called by muse, mutect2, varscan2
- ZPLD1 | c.1155C>T p.S385= (on ENST00000466937 / NM_001329788.1; = p.S401= on NM_175056.2) | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV60351886; called by muse, varscan2
- DNAJC11 | c.*989C>T | 3'UTR (SNP) | VAF 6/9 reads (67%) | called by muse, mutect2, varscan2
- TRPM3 | c.979+16620T>C | Intron (SNP) | VAF 3/22 reads (14%) | called by muse, varscan2
